MMRF case MMRF_2461 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/42e8c7ec-70d1-43ab-bf46-ee01eda4f8b6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 87 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 87.3 years (31,872 days); ISS stage: II; Days to last known disease status: 711 days (1.9 years); Days to last follow up: 711 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 491 days (1.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 504 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone + Ixazomib + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 505 days (1.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14 (ECOG 2): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 62.3 mg/dL; Immunoglobulin G 48 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 4.2 µg/mL; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.57 mmol/L; Albumin 31 g/L; Total Protein 9 g/dL; Glucose 4.95 mmol/L.
- Day 70 (ECOG 2): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.4 mg/dL; Immunoglobulin G 20.8 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 4.2 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.37 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.5 mmol/L.
- Day 175 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.89 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 4.95 mmol/L.
- Day 252 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.16 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 6.8 g/dL; Glucose 4.13 mmol/L.
- Day 336 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.63 mg/dL; Immunoglobulin G 15.5 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 7.1 g/dL; Glucose 6.49 mmol/L.
- Day 420 (ECOG 1): Lactate Dehydrogenase 3 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 128 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.13 mmol/L; Albumin 30 g/L; Total Protein 7.2 g/dL; Glucose 7.04 mmol/L.
- Day 541 (ECOG 1): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 37.9 mg/dL; Immunoglobulin G 27.8 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 4.3 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 6.6 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 15.4 mmol/L; Calcium 2.1 mmol/L; Albumin 24 g/L; Total Protein 6.7 g/dL; Glucose 5.56 mmol/L.
- Day 627 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.19 mg/dL; Immunoglobulin G 9.84 g/L; Immunoglobulin A 2.28 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.13 mmol/L; Albumin 31 g/L; Total Protein 6.7 g/dL; Glucose 6.11 mmol/L.
- Day 711 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.38 mg/dL; Immunoglobulin G 8.25 g/L; Immunoglobulin A 2.45 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 59 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 16.8 mmol/L; Calcium 2.13 mmol/L; Albumin 27 g/L; Total Protein 6.5 g/dL; Glucose 5.89 mmol/L.

Other clinical attributes
- Day -14: Weight: 40 kg; Height: 159 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_2461_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -14 days.
- Sample MMRF_2461_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -14 days.
